Surgical pathology report (de-identified scan), TCGA case TCGA-34-5232, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-34-5232-01A (Primary Tumor).

FINAL DIAGNOSIS:

Summary Statement

The left upper lobectomy demonstrates an in situ and invasive moderately-differentiated squamous cell carcinoma associated with angiolymphatic invasion, but without visceral pleural invasion with involvement of one of twenty (1/20) N1 lymph nodes and zero of eleven (0/11) N2 lymph nodes. All margins free. Pathologic stage: T1 N1 MX.

PART 1: LYMPH NODE, SUBCARINAL LYMPH NODE, BIOPSY –
SEVEN (7) FRAGMENTS OF LYMPH NODE WITH NO EVIDENCE OF METASTATIC CARCINOMA.

PART 2: LYMPH NODE, RIGHT TRACHEOBRONCHIAL ANGLE LYMPH NODE, BIOPSY –
THREE (3) FRAGMENTS OF LYMPH NODE WITH NO EVIDENCE OF METASTATIC CARCINOMA.

PART 3: LYMPH NODE, RIGHT PARATRACHEAL LYMPH NODE, BIOPSY –
TWO (2) FRAGMENTS OF LYMPH NODE WITH NO EVIDENCE OF METASTATIC CARCINOMA.

PART 4: RIB, "PORTION OF RIB", PARTIAL RESECTION –
SPECIMEN UNDERGOING DECALCIFICATION, ADDENDUM REPORT TO FOLLOW.

PART 5: LYMPH NODE, INFERIOR PULMONARY LIGAMENT LYMPH NODE, BIOPSY –
THREE (3) FRAGMENTS OF LYMPH NODE WITH NO EVIDENCE OF METASTATIC CARCINOMA.

PART 6: LYMPH NODE, ANTERIOR HILAR LYMPH NODE, BIOPSY –
TWO (2) FRAGMENTS OF WITH NO EVIDENCE OF METASTATIC CARCINOMA.

PART 7: LYMPH NODE, RIGHT UPPER LOBE LYMPH NODE, BIOPSY –
ONE OF TWO NODES WITH METASTATIC SQUAMOUS CELL CARCINOMA (1/2).

PART 8: LYMPH NODE, INTRALOBAR LYMPH NODE, BIOPSY –
SOLITARY LYMPH NODE WITH NO EVIDENCE OF METASTATIC CARCINOMA (0/1).

PARTS 9

AND 12: LUNG, LEFT UPPER LOBE, WEDGE RESECTION WITH SUBSEQUENT COMPLETION LOBECTOMY –

- A. IN SITU AND INVASIVE MODERATELY-DIFFERENTIATED SQUAMOUS CELL CARCINOMA WITH PROMINENT ENDOBRONCHIAL COMPONENT AND ASSOCIATED WITH ANGIOLYMPHATIC INVASION. DIAMETER 2.0 CM. NO EVIDENCE OF VISCERAL PLEURAL INVASION. ALL MARGINS FREE. MARKED HOST LYMPHOCYTIC RESPONSE. PATHOLOGIC STAGE: T1 N1 MX.
- B. NINE N1 LYMPH NODES WITH NO EVIDENCE OF METASTATIC CARCINOMA (0/9).
- C. MILD EMPHYSEMATOUS CHANGE.
- D. FOCAL POSTOBSTRUCTIVE PNEUMONIA AND BRONCHIECTASIS.

PART 10: LYMPH NODE, POSTERIOR LEFT UPPER LOBE BRONCHUS LYMPH NODE, BIOPSY –
SOLITARY LYMPH NODE WITH NO EVIDENCE OF METASTATIC CARCINOMA (0/1).

PART 11: LYMPH NODE, INTRALOBAR LYMPH NODE, BIOPSY –
SOLITARY LYMPH NODE WITH NO EVIDENCE OF METASTATIC CARCINOMA (0/1).

PART 13: LYMPH NODE, AP WINDOW LYMPH NODE, BIOPSY –
SOLITARY LYMPH NODE WITH NO EVIDENCE OF METASTATIC CARCINOMA (0/1).

PART 14: LYMPH NODE, PERIAORTIC LYMPH NODE, BIOPSY –
THREE (3) FRAGMENTS OF LYMPH NODE WITH NO EVIDENCE OF METASTATIC CARCINOMA.

PART 15: LYMPH NODE, POSTERIOR HILAR LYMPH NODE, BIOPSY –
SOLITARY LYMPH NODE WITH NO EVIDENCE OF METASTATIC CARCINOMA (0/1).

Addendum

Sections of the part 4 "portion of rib" show a normal bone and bone marrow with trilineage representation and maturation and no evidence of metastatic carcinoma. ✓

Source: NCI Genomic Data Commons file f94b1aa7-bb3e-45f0-81e0-83e67c6f7b81 (TCGA-34-5232.5B40BF87-DE4D-4010-934F-B117F286562F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).